Somatic mutation profile of tumor specimen TARGET-40-PATJVI-01A (aliquot TARGET-40-PATJVI-01A-01D) from TARGET case TARGET-40-PATJVI, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.8 years (5,755 days).
Specimen TARGET-40-PATJVI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3507a16-a889-4ee9-8fee-15ffa4b027af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PATJVI-10A (Blood Derived Normal), aliquot TARGET-40-PATJVI-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/709f07fd-885b-4058-b787-739bfe34aac8

The open-access MAF lists 31 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 4, Silent 4, RNA 4, 3'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD37 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs778370014, COSV60544255; called by muse, mutect2, varscan2
- CHRNE | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773916039; called by muse, mutect2, varscan2
- GBP6 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100969436, COSV100969734; called by muse, mutect2, varscan2
- P2RX3 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 184/321 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754831763, COSV99555225; called by muse, mutect2, varscan2
- PCDHGB6 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV53899923; called by mutect2, varscan2
- PPP2R1B | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs377516814, COSV100232363; called by muse, mutect2, varscan2
- SNRPC | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99765363; called by muse, mutect2, varscan2
- ACSS1 | c.1801A>T p.S601C | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2
- CHEK1 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- LRRK2 | c.4778G>C p.S1593T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.276); called by muse, mutect2
- MYH1 | c.1323G>A p.W441* | Nonsense Mutation (SNP) | VAF 299/510 reads (59%) | called by muse, mutect2, varscan2
- PGM1 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2G7 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- RBFA | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SPOCK3 | c.782A>T p.D261V | Missense Mutation (SNP) | VAF 79/137 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UXS1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR72 | c.2074C>G p.L692V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GPR15 | c.603T>C p.I201= | Silent (SNP) | VAF 107/131 reads (82%) | called by muse, mutect2, varscan2
- LDHD | c.837C>T p.V279= | Silent (SNP) | VAF 60/123 reads (49%) | called by muse, mutect2, varscan2
- MED23 | c.1803A>G p.L601= | Silent (SNP) | VAF 56/77 reads (73%) | called by muse, mutect2, varscan2
- NBPF10 | c.1134C>G p.T378= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs74428101, COSV61656518; called by mutect2, varscan2
- ARHGAP32 | c.*2C>T | 3'UTR (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- FAM189A1 | c.388-55C>T | Intron (SNP) | VAF 40/44 reads (91%) | called by muse, mutect2, varscan2
- PRKACB | c.47-14797T>A | Intron (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- VSX1 | c.627+180T>A | Intron (SNP) | VAF 71/79 reads (90%) | called by muse, mutect2
- VWFP1 | n.2113C>T | RNA (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- VWFP1 | n.1844C>T | RNA (SNP) | VAF 44/80 reads (55%) | called by muse, varscan2
- VWFP1 | n.1554C>T | RNA (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2
- VWFP1 | n.851C>G | RNA (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- WASH6P | c.720+82G>T | Intron (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49278708 G>A | 5'Flank (SNP) | VAF 31/219 reads (14%) | called by muse, mutect2, varscan2
